Surgical pathology report (de-identified scan), TCGA case TCGA-B8-A54G, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-A54G-01A (Primary Tumor).

[page 1 of 2]
ICD0-3

Carcinoma, renal cell, NOS
Clear Cell type 831213

Site: (R) Kidney, NOS
C64.9
11/30/12

Diagnosis:

Kidney, right robotic partial nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, clear cell type

Histologic grade (if applicable): Fuhrman grade 3 (of 4)

Sarcomatoid features: not identified

Tumor size (greatest dimension): 2.5 cm

Tumor focality: solitary

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: not identified

Major veins (renal vein or segmental branches, IVC): not identified

Venous (large vessel): not identified

Lymphatic (small vessel): focally present microscopically (A5)

Histologic assessment of surgical margins:

Renal parenchymal margin: negative

Renal capsular margin: negative

Perinephric adipose tissue margin: not applicable

Lymph nodes: no lymph nodes submitted

Other significant findings: separate partial nephrectomy with benign simple cyst, 1 cm

AJCC Staging:

pT1a pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

year-old male with renal mass.

[page 2 of 2]
Gross Description:

Received is one appropriately labeled container, additionally labeled "1. Tumor kidney, 2. kidney tumor" and consists of two partial nephrectomy specimens 2 grams (1.5 x 1.5 x 0.6 cm) and 20 grams (3.7 x 3.7 x 3.5 cm). The capsule and parenchymal margin of each segment is inked black and blue respectively. Adherent to the capsule of the smaller segment is a 1.0 x 1.0 x 0.7 cm intact, partially collapsed simple cyst. The cyst is filled with a thin brown fluid. The cyst wall is <0.1 cm thick and without excrescences. The parenchyma is unremarkable. The specimen is submitted in A1 and A2,

The cut surface of the larger segment has a 2.5 x 2.5 x 2.5 cm well-circumscribed soft variegated mass that bulges the capsule, but does not extend through it and is 0.1 cm from the parenchymal margin. The uninvolved parenchyma is smooth and tan/brown. A portion of tumor is given to tissue procurement.

Block Summary:

- A3-A4 - Mass closest to the parenchymal margin, perpendicular
- A5-A6 - Mass abutting capsule
- A7 - Mass with adjacent normal kidney

12/4/12

Dis/Synchronous Primary	Noted	
Reviewed: [Signature]	Date reviewed: 12/5/12	

Source: NCI Genomic Data Commons file 9e9e880e-7fb4-4a2c-bd96-5b42ea2c6b20 (TCGA-B8-A54G.FCE3B3CB-A0E9-496B-871E-7A82AC4FA392.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).